CCDI case PBCKDS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/46f216e4-c1b2-4e0b-97ef-306d2b6dda46

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.7 years (2,821 days).

Biospecimens (3 samples)
- Sample 0DTYAM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTYAW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTYB8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
